Somatic mutation profile of tumor specimen 0DM1K1 from CCDI case PBBZIE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 14.6 years (5,326 days).
Specimen 0DM1K1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a3e9ac9-4920-4f4f-ba48-51327c6515d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM1JB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f68b60b4-b45f-48ef-91ef-a68af63dca79

The open-access MAF lists 50 somatic variants for this specimen: 32 protein-altering or splice-affecting, 8 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Intron 8, Silent 8, Frame Shift Ins 2, In Frame Del 1, Frame Shift Del 1, 5'UTR 1, 3'UTR 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNRNPK | c.931_932insTT p.P311Lfs*40 | Frame Shift Ins (INS) | VAF 255/755 reads (34%) | catalogued as rs879255263; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 615/1061 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRF1 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 99/583 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as rs144088839; called by muse, mutect2, varscan2
- CEP290 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 81/978 reads (8%) | catalogued as rs752144368; called by muse, mutect2
- FAM167A | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 99/479 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1333723238, COSV52704392; called by muse, mutect2, varscan2
- KIF21A | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 239/964 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770246874; called by muse, mutect2, varscan2
- MLXIP | c.2636C>T p.P879L | Missense Mutation (SNP) | VAF 116/454 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1473149382, COSV59836777; called by muse, mutect2, varscan2
- OR5F1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 252/800 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs190524347, COSV53546231; called by muse, mutect2, varscan2
- PIWIL4 | c.1570A>G p.K524E | Missense Mutation (SNP) | VAF 135/488 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1486832216; called by muse, mutect2, varscan2
- POLE | c.1270C>T p.L424F | Missense Mutation (SNP) | VAF 167/742 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs483352909, CM1212502, COSV57673603, COSV57691098; called by muse, mutect2, varscan2
- RIN3 | c.2632-4G>A | Splice Region (SNP) | VAF 72/471 reads (15%) | catalogued as rs993716600; called by muse, mutect2, varscan2
- SPSB2 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 145/615 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1555133744, COSV51289986; called by muse, mutect2, varscan2
- TJP1 | c.5030G>A p.R1677Q | Missense Mutation (SNP) | VAF 62/419 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as rs759442574, COSV62044335, COSV62046680; called by muse, mutect2, varscan2
- TMEM41B | c.829A>G p.I277V | Missense Mutation (SNP) | VAF 117/773 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs777720169; called by muse, mutect2, varscan2
- TNF | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 230/666 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as rs763000109; called by muse, mutect2, varscan2
- ANK3 | c.5584G>A p.E1862K | Missense Mutation (SNP) | VAF 119/1161 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ASXL2 | c.1948A>C p.N650H | Missense Mutation (SNP) | VAF 225/865 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- B4GALNT3 | c.2173_2179dup p.E727Afs*37 | Frame Shift Ins (INS) | VAF 159/736 reads (22%) | called by mutect2, varscan2
- CALU | c.122A>G p.D41G | Missense Mutation (SNP) | VAF 187/1372 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CFAP73 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 111/479 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CFAP73 | c.458T>G p.L153R | Missense Mutation (SNP) | VAF 107/474 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOK7 | c.568del p.E190Sfs*56 | Frame Shift Del (DEL) | VAF 190/552 reads (34%) | called by mutect2, pindel, varscan2
- GPT2 | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 110/637 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- HIVEP1 | c.6595G>A p.A2199T | Missense Mutation (SNP) | VAF 32/507 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.113); called by muse, mutect2
- ITPR2 | c.6849G>C p.K2283N | Missense Mutation (SNP) | VAF 85/1147 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); called by muse, mutect2
- KMT2E | c.1827A>T p.K609N | Missense Mutation (SNP) | VAF 125/1046 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- MUC16 | c.21539A>T p.N7180I | Missense Mutation (SNP) | VAF 118/757 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- OR9G4 | c.535T>C p.C179R | Missense Mutation (SNP) | VAF 262/745 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STK17B | c.98_103del p.I33_L34del | In Frame Del (DEL) | VAF 169/718 reads (24%) | called by mutect2, pindel, varscan2
- TJP1 | c.4501C>A p.Q1501K | Missense Mutation (SNP) | VAF 140/675 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VEZT | c.1796G>C p.R599T | Missense Mutation (SNP) | VAF 279/1213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VPS13B | c.9181G>A p.G3061S | Missense Mutation (SNP) | VAF 223/945 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ARHGEF5 | c.4288C>A p.R1430= | Silent (SNP) | VAF 21/133 reads (16%) | called by mutect2, varscan2
- CACNG5 | c.78C>T p.I26= | Silent (SNP) | VAF 153/477 reads (32%) | catalogued as rs769615801, COSV50056602; called by muse, mutect2, varscan2
- ELMO1 | c.684C>A p.L228= | Silent (SNP) | VAF 97/981 reads (10%) | called by muse, mutect2, varscan2
- EVPL | c.1383C>T p.P461= | Silent (SNP) | VAF 170/503 reads (34%) | catalogued as rs147884038; called by muse, mutect2, varscan2
- IRF2BP1 | c.933G>A p.S311= | Silent (SNP) | VAF 64/453 reads (14%) | catalogued as rs765970337, COSV56193254; called by muse, mutect2, varscan2
- KLF4 | c.531C>T p.S177= | Silent (SNP) | VAF 122/336 reads (36%) | catalogued as rs758595779; called by muse, mutect2, varscan2
- SLCO1C1 | c.1416C>A p.L472= | Silent (SNP) | VAF 214/991 reads (22%) | called by muse, mutect2, varscan2
- UNC13C | c.4206C>A p.S1402= | Silent (SNP) | VAF 104/495 reads (21%) | called by mutect2, varscan2
- AGPAT4 | c.348+89T>G | Intron (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
- BRCA2 | c.9502-52_9502-51del | Intron (DEL) | VAF 95/407 reads (23%) | called by mutect2, pindel, varscan2
- CYP4F3 | c.918+18C>A | Intron (SNP) | VAF 136/576 reads (24%) | called by muse, mutect2, varscan2
- DCT | c.595+25T>C | Intron (SNP) | VAF 46/958 reads (5%) | called by muse, mutect2
- E2F5 | c.*82A>G | 3'UTR (SNP) | VAF 46/512 reads (9%) | called by muse, mutect2
- PPWD1 | c.-5A>G | 5'UTR (SNP) | VAF 20/502 reads (4%) | catalogued as COSV54335683; called by muse, mutect2
- SEC23A | c.1987-64A>G | Intron (SNP) | VAF 64/194 reads (33%) | called by muse, mutect2
- SPTBN4 | c.7494-44G>A | Intron (SNP) | VAF 174/570 reads (31%) | catalogued as rs746041169; called by muse, mutect2, varscan2
- TMEM94 | c.144+15C>T | Intron (SNP) | VAF 117/346 reads (34%) | catalogued as rs371829395; called by muse, mutect2, varscan2
- WDR27 | c.332-46C>T | Intron (SNP) | VAF 61/371 reads (16%) | catalogued as COSV100360188; called by muse, mutect2, varscan2
